Somatic mutation profile of tumor specimen MP2PRT-PARNFI-TMP1-A (aliquot MP2PRT-PARNFI-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PARNFI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Precursor B-cell lymphoblastic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,327 days).
Specimen MP2PRT-PARNFI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32685251-145a-45d9-9548-ce51f5647c10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARNFI-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARNFI-NM1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d363abb-8c7f-45b7-8594-62952dc03c82

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MGRN1 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs889925387; called by muse, mutect2
- MUC5B | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 46/622 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs374678634, COSV71591396; called by muse, mutect2
- SLC4A9 | c.736C>T p.R246* (on ENST00000507527 / NM_001258428.2; = p.R222* on NM_031467.3) | Nonsense Mutation (SNP) | VAF 140/383 reads (37%) | catalogued as rs1045269384; called by muse, mutect2, varscan2
- TNMD | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as rs1022077772; called by muse, mutect2, varscan2
- XKR5 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 100/329 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781636373; called by muse, mutect2, varscan2
- ADCY2 | c.2524C>T p.R842W | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2
- IGKV2D-24 | chr2:90005628 CTCA>TCCAGGAGACC | Missense Mutation (INS) | VAF 32/165 reads (19%) | called by pindel, varscan2*
- MROH2B | c.1224G>T p.R408S | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.055); called by muse, mutect2
- MXD3 | c.197A>G p.E66G | Missense Mutation (SNP) | VAF 33/447 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC4A10 | c.1054T>C p.L352= (on ENST00000446997 / NM_001354461.2; = p.L322= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 19/373 reads (5%) | catalogued as rs1056665152; called by muse, mutect2
- IGHV3-53 | chr14:106592675 ins GCCTA | 3'Flank (INS) | VAF 22/120 reads (18%) | called by mutect2, pindel, varscan2
